MMRF case MMRF_2419 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/175138f4-b09b-4528-96fb-2a22cfcecd2b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.4 years (20,236 days); ISS stage: III; Days to last known disease status: 716 days (2.0 years); Days to last follow up: 716 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 162 days; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Bortezomib + Carfilzomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 519 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 716.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 4.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.726 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 45.5 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 5.6 µg/mL; Lactate Dehydrogenase 4.32 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.62 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.68 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 10 g/dL.
- Day 93: Immunoglobulin G 2.85 g/L; Immunoglobulin A 27.4 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.2 mmol/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 146 ×10⁹/L; Blood Urea Nitrogen 7.21 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 8.1 g/dL; Glucose 5.61 mmol/L.
- Day 162: M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.196 mg/dL; Immunoglobulin G 2.33 g/L; Immunoglobulin A 21.4 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 0.9 µg/mL; Hemoglobin 6.51 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 5.45 mmol/L.
- Day 269: Serum Free Immunoglobulin Light Chain, Kappa 2.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.889 mg/dL; Immunoglobulin G 4.08 g/L; Immunoglobulin A 3.69 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.03 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 4.62 mmol/L.
- Day 348: Serum Free Immunoglobulin Light Chain, Kappa 0.721 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.853 mg/dL; Immunoglobulin G 5.44 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.07 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL.
- Day 450: Hemoglobin 7.87 mmol/L; Leukocytes 2.5 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.95 mmol/L; Albumin 33 g/L; Glucose 7.15 mmol/L.
- Day 681: Serum Free Immunoglobulin Light Chain, Kappa 3.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day -10: Weight: 98 kg; Height: 184 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples)
- Sample MMRF_2419_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2419_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
- Sample MMRF_2419_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 162 days.
